Gene-level copy-number profile of tumor specimen TCGA-44-6775-01C from TCGA case TCGA-44-6775, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.3 years (26,415 days).
Specimen TCGA-44-6775-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1a6264c2-434f-447d-918f-67bc2cd015ac.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-6775-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 355 have no estimate.
https://portal.gdc.cancer.gov/files/cc83d827-1789-4725-8d2f-33c5ef6c608c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 600; copy number 2: 59,165; copy number 3: 462; copy number 4: 27; copy number 5: 7; copy number 6: 5; copy number 13: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-6775-01A-11D-A273-01): tumor purity 0.27, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:28,651,732–28,653,208, 1 gene (within-gene range 0–2): ARIH2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:201,719,508–201,719,627, 1 gene, copy number 13: MIR5191.
- chr2:76,684,975–76,698,996, 2 genes, copy number 6 (within-gene range 2–6): AC068616.3, AC068616.1.
- chr6:5,997,999–6,007,605, 1 gene, copy number 6: NRN1.
- chr7:23,181,841–23,201,011, 1 gene, copy number 6: NUP42.
- chr7:121,419,072–121,419,845, 1 gene, copy number 6: AC074085.1.
- chr8:18,979,619–19,000,952, 2 genes, copy number 5 (within-gene range 2–5): SNORA62, AC009884.1.
- chr11:102,313,722–102,328,586, 2 genes, copy number 5: RNU6-952P, AP000942.5.
- chr12:53,097,436–53,124,535, 2 genes, copy number 5 (within-gene range 2–5): IGFBP6, SOAT2.

Autosomal genes at a single copy (total copy number 1): 68. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
